Somatic mutation profile of tumor specimen TCGA-V4-A9EM-01A (aliquot TCGA-V4-A9EM-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EM, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.1 years (19,413 days).
Specimen TCGA-V4-A9EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe91062b-0000-45f5-8554-72f0363a2d1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EM-10A (Blood Derived Normal), aliquot TCGA-V4-A9EM-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d4f5712-7f43-425f-bbca-12b7679ef03d

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 55/101 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.274_297del p.Y92_H99del | In Frame Del (DEL) | VAF 12/52 reads (23%) | hotspot (GDC flag); called by mutect2, pindel
- EIF1B | c.60C>G p.D20E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV51763150; called by muse, mutect2, varscan2
- MAP1S | c.396_397del p.G134Lfs*40 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs752646082; called by mutect2, pindel, varscan2
- MARCHF6 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs1207274476, COSV99929529; called by muse, mutect2, varscan2
- MYBPC2 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765476587, COSV63094943; called by muse, mutect2, varscan2
- SETD2 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 87/201 reads (43%) | catalogued as rs976581260, COSV57434358; called by muse, mutect2, varscan2
- VWF | c.4345C>G p.Q1449E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV54611598; called by muse, mutect2, varscan2
- ACD | c.865C>G p.P289A (on ENST00000620338; = p.P200A on NM_022914.3) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP17 | c.1756G>C p.A586P (on ENST00000289968 / NM_001006634.3; = p.A508P on NM_018054.6) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL25A1 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HHAT | c.99A>T p.E33D | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- MAPKAPK2 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBN | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- RHPN2 | c.244T>A p.S82T | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- E2F2 | c.150G>A p.P50= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- RSPH4A | c.771A>G p.Q257= | Silent (SNP) | VAF 66/242 reads (27%) | catalogued as rs1562389892; called by muse, mutect2, varscan2
